Somatic mutation profile of tumor specimen 0DYV0X from CCDI case PBCSWK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 22.2 years (8,112 days).
Specimen 0DYV0X: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5bc6bf68-cedc-4151-96c2-15915dd9f322.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DYV1C (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e17f9cd-a1ad-4483-a411-a6b87897f0ae

The open-access MAF lists 21 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, Intron 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.526T>C p.C176R | Missense Mutation (SNP) | VAF 378/799 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs967461896, CM165714, COSV52681947, COSV52682539, COSV52736779, COSV52752470; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- BMS1 | c.3238G>C p.G1080R | Missense Mutation (SNP) | VAF 719/1712 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV65732800; called by muse, mutect2, varscan2
- CCDC136 | c.2441A>G p.Y814C | Missense Mutation (SNP) | VAF 113/593 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs373049285; called by muse, mutect2, varscan2
- SHISA9 | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 168/1015 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1226938626, COSV69631698; called by muse, mutect2, varscan2
- TTN | c.76750G>A p.V25584I (on ENST00000591111; = p.V18160I on NM_003319.4) | Missense Mutation (SNP) | VAF 261/1407 reads (19%) | PolyPhen benign (0.073); catalogued as rs375211424; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF280B | c.70G>C p.D24H | Missense Mutation (SNP) | VAF 555/1382 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.891); catalogued as COSV100840236; called by muse, mutect2, varscan2
- AMDHD2 | c.7G>A p.G3S | Missense Mutation (SNP) | VAF 805/2056 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CADM1 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 242/1027 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCMF1 | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 421/1127 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- MLF2 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 153/739 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PTPRK | c.2339C>G p.A780G (on ENST00000368215 / NM_001291984.2; = p.A781G on NM_002844.4) | Missense Mutation (SNP) | VAF 269/713 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TUT1 | c.2359C>G p.Q787E | Missense Mutation (SNP) | VAF 295/555 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- UBR4 | c.9788C>T p.A3263V | Missense Mutation (SNP) | VAF 246/1288 reads (19%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- C11orf95 | c.1311G>C p.L437= | Silent (SNP) | VAF 268/528 reads (51%) | called by muse, mutect2, varscan2
- C11orf95 | c.1185G>A p.E395= | Silent (SNP) | VAF 684/1441 reads (47%) | called by muse, mutect2, varscan2
- LRRFIP1 | c.1797G>T p.R599= | Silent (SNP) | VAF 347/945 reads (37%) | called by muse, mutect2, varscan2
- NOS1 | c.1671G>A p.E557= | Silent (SNP) | VAF 280/537 reads (52%) | called by muse, mutect2, varscan2
- OR1N1 | c.816A>T p.A272= | Silent (SNP) | VAF 26/346 reads (8%) | called by muse, mutect2
- C15orf40 | c.*33T>C | 3'UTR (SNP) | VAF 33/774 reads (4%) | catalogued as rs1176371346; called by muse, mutect2
- HMG20B | c.472+35C>A | Intron (SNP) | VAF 25/455 reads (5%) | catalogued as rs1362730924; called by muse, mutect2
- PDAP1 | c.213+23T>C | Intron (SNP) | VAF 144/367 reads (39%) | called by muse, mutect2, varscan2
